Somatic mutation profile of tumor specimen TCGA-CH-5746-01A (aliquot TCGA-CH-5746-01A-11D-1576-08) from TCGA case TCGA-CH-5746, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-CH-5746-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff66ba2-6757-47b5-aee8-cde5575ab2d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5746-10A (Blood Derived Normal), aliquot TCGA-CH-5746-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76e22c9a-d70a-4520-8a51-cd27c055ad7e

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCN1 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71704344; called by muse, mutect2, varscan2
- CHPF | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.279); catalogued as COSV60534803; called by muse, mutect2
- DPYSL2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV60783506; called by muse, mutect2, varscan2
- NCAM2 | c.2021A>G p.Y674C | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as rs762364321, COSV53076038; called by muse, mutect2, varscan2
- NOX5 | c.2172C>A p.F724L | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV52989118; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.995G>C p.G332A | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57965219; called by muse, mutect2, varscan2
- SLCO1B1 | c.902C>A p.T301K | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV57011371; called by muse, mutect2, varscan2
- TBX18 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 99/538 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571410094, COSV63736132; called by muse, mutect2, varscan2
- CYP2R1 | c.128dup p.P44Afs*50 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- JADE2 | c.1842G>A p.G614= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV50916479; called by muse, mutect2
- ZNF683 | c.708G>T p.L236= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV62874346; called by muse, mutect2, varscan2
